Somatic mutation profile of tumor specimen TCGA-39-5034-01A (aliquot TCGA-39-5034-01A-01D-1441-08) from TCGA case TCGA-39-5034, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.1 years (26,682 days).
Specimen TCGA-39-5034-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c0a905-2bec-4617-bb9b-613070a0029f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5034-11A (Solid Tissue Normal), aliquot TCGA-39-5034-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d930d718-c704-4188-abae-7f49ede4f46e

The open-access MAF lists 624 somatic variants for this specimen: 469 protein-altering or splice-affecting, 141 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 387, Silent 141, Nonsense Mutation 41, Splice Site 19, Frame Shift Del 14, RNA 4, Intron 3, 3'UTR 3, Splice Region 3, Frame Shift Ins 2, 3'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 41/73 reads (56%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.1955G>T p.W652L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741719; called by muse, mutect2, varscan2
- ABCA13 | c.13789A>G p.K4597E | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs756778938, COSV101291222; called by muse, mutect2, varscan2
- ABCB5 | c.1707G>T p.K569N (on ENST00000404938 / NM_001163941.2; = p.K124N on NM_178559.6) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs770338019, COSV99327723; called by muse, mutect2, varscan2
- ABCC11 | c.3263C>A p.A1088E | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV62325835; called by muse, mutect2, varscan2
- ACSM3 | c.219+1G>A p.X73_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as rs772081676, COSV99184137; called by muse, mutect2
- ACSM5 | c.1729T>A p.W577R | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100088568; called by mutect2, varscan2
- ACTA1 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100796709; called by muse, mutect2, varscan2
- ACTN3 | c.2125C>G p.L709V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100074160; called by muse, mutect2, varscan2
- ADAMDEC1 | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99835889; called by muse, mutect2, varscan2
- ADAMTS16 | c.2834G>C p.G945A | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV99940439; called by muse, mutect2, varscan2
- ADAMTS17 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99170415; called by muse, mutect2, varscan2
- ADAMTS17 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768922225, COSV99170417; called by muse, mutect2, varscan2
- ADAR | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs1403677320, COSV52713510, COSV99425636; called by muse, mutect2, varscan2
- ADCY10 | c.2395G>A p.G799S | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.355); catalogued as COSV100896652; called by muse, varscan2
- ADCY2 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100602104; called by muse, mutect2, varscan2
- AGAP3 | c.1942+2T>G p.X648_splice (on ENST00000622464; = p.X684_splice on NM_031946.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 77/138 reads (56%) | catalogued as COSV101257025; called by muse, mutect2, varscan2
- AKAP6 | c.6397A>T p.S2133C | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99799122; called by muse, mutect2, varscan2
- AMER3 | c.1481T>A p.L494Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100366151; called by muse, mutect2, varscan2
- ANK3 | c.4025T>C p.L1342S (on ENST00000280772 / NM_001320874.2; = p.L476S on NM_001149.3) | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99778816; called by muse, mutect2, varscan2
- ANKRD27 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100042622; called by muse, mutect2
- ANKRD30A | c.1040C>A p.S347Y (on ENST00000611781; = p.S291Y on NM_052997.2) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.962); catalogued as COSV100653080; called by muse, mutect2, varscan2
- ANO10 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV99428252; called by muse, mutect2, varscan2
- ANO5 | c.1913G>T p.W638L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.11); catalogued as COSV100201545; called by muse, mutect2, varscan2
- ANO5 | c.1914G>T p.W638C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61091439; called by muse, mutect2, varscan2
- ANO7 | c.1142+1G>A p.X381_splice (on ENST00000274979; = p.X327_splice on NM_001370694.2) | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as rs372312433, COSV51468114; called by muse, mutect2
- ANO7 | c.1465C>A p.P489T (on ENST00000274979; = p.P435T on NM_001370694.2) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV99237721; called by muse, mutect2, varscan2
- ANP32E | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100029592; called by muse, mutect2, varscan2
- APBB1IP | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 75/170 reads (44%) | catalogued as COSV100770882; called by muse, mutect2, varscan2
- ASTL | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100668271; called by muse, mutect2, varscan2
- ASTN1 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56074994, COSV99920784; called by muse, mutect2, varscan2
- ASTN2 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV57748006, COSV57776763; called by muse, mutect2, varscan2
- ATAD2 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV99784248; called by muse, varscan2
- ATG13 | c.1384G>T p.D462Y (on ENST00000359513 / NM_001346321.1; = p.D425Y on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100365546; called by muse, mutect2, varscan2
- ATP10B | c.1907C>A p.S636* | Nonsense Mutation (SNP) | VAF 91/215 reads (42%) | catalogued as COSV100514372; called by muse, mutect2, varscan2
- ATP10B | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100469168; called by muse, mutect2, varscan2
- BCL2L1 | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100304613, COSV100304618; called by muse, mutect2, varscan2
- BIRC6 | c.13616C>T p.T4539M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372630615; called by muse, mutect2
- BOD1L1 | c.8888C>A p.S2963Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV99238720; called by muse, mutect2, varscan2
- BOD1L1 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50045680, COSV99238729; called by muse, varscan2
- BPTF | c.7819G>C p.V2607L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as COSV100074341; called by muse, mutect2, varscan2
- BRAT1 | c.1966G>T p.E656* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100500375, COSV61394410; called by muse, mutect2, varscan2
- BRCA2 | c.635G>T p.R212I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as CD021788, COSV101204004; called by muse, mutect2, varscan2
- BRINP3 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV100818460; called by muse, mutect2, varscan2
- BRWD3 | c.2639G>T p.R880L | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100955776; called by muse, mutect2, varscan2
- C6 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 73/137 reads (53%) | catalogued as COSV54704397, COSV99666704; called by muse, mutect2, varscan2
- C7orf61 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100190205; called by muse, mutect2
- CACNA1E | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV100701474, COSV62412818; called by muse, mutect2, varscan2
- CACNA1E | c.6450C>G p.S2150R (on ENST00000367573 / NM_001205293.3; = p.S2107R on NM_000721.4) | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100701475; called by muse, varscan2
- CACNA1I | c.2555T>A p.V852E | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100359505; called by muse, mutect2, varscan2
- CACNG6 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 83/416 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV99403320; called by muse, mutect2, varscan2
- CALCA | c.227+2T>C p.X76_splice | Splice Site (SNP) | VAF 46/173 reads (27%) | catalogued as COSV100523948; called by muse, mutect2, varscan2
- CAMTA1 | c.2908T>A p.L970M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100347135; called by muse, mutect2, varscan2
- CAPSL | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV68438473; called by muse, varscan2
- CARD8 | c.1002G>T p.L334F (on ENST00000651546 / NM_001184900.3; = p.L284F on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1308016079, COSV100751029; called by muse, mutect2, varscan2
- CCDC8 | c.1169A>T p.N390I | Missense Mutation (SNP) | VAF 408/609 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100281935; called by muse, mutect2, varscan2
- CDH7 | c.1867T>C p.L623= | Splice Region (SNP) | VAF 16/75 reads (21%) | catalogued as COSV100541659; called by muse, mutect2, varscan2
- CDH7 | c.2358G>T p.*786Yext*? (on ENST00000323011 / NM_033646.3; = p.*786Yext*21 on NM_004361.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100541662; called by muse, mutect2, varscan2
- CDHR2 | c.180T>A p.Y60* | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as COSV99991186; called by muse, mutect2, varscan2
- CEP128 | c.2597G>T p.W866L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99823936; called by muse, mutect2, varscan2
- CERT1 | c.1537A>G p.S513G (on ENST00000405807 / NM_001130105.1; = p.S385G on NM_005713.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as COSV99782982; called by muse, mutect2, varscan2
- CFAP61 | c.1250A>T p.K417M | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV99843767; called by muse, mutect2, varscan2
- CFH | c.2233G>T p.V745L | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100809068; called by muse, mutect2, varscan2
- CHAF1A | c.1787A>G p.Y596C | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010935; called by muse, mutect2, varscan2
- CLEC4F | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV55481873, COSV99713604; called by muse, mutect2, varscan2
- CLIP2 | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99791168; called by muse, mutect2, varscan2
- CMTR2 | c.1310G>C p.R437T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100579036; called by muse, mutect2, varscan2
- CNKSR3 | c.1105A>T p.S369C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV101401261, COSV101401307; called by muse, mutect2, varscan2
- CNTN4 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100638949; called by muse, mutect2, varscan2
- CNTN4 | c.1402A>T p.T468S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.31); catalogued as COSV100638950; called by muse, mutect2, varscan2
- CNTNAP5 | c.3850G>T p.D1284Y | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.707); catalogued as COSV101443144; called by muse, mutect2, varscan2
- COL11A1 | c.2017G>T p.G673C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762115241, COSV100615019; called by muse, mutect2, varscan2
- COL24A1 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100992941, COSV100993035; called by muse, mutect2, varscan2
- COL3A1 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV58588741; called by muse, mutect2, varscan2
- COL5A2 | c.3793G>C p.D1265H | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100880073, COSV66408805; called by muse, mutect2, varscan2
- CPED1 | c.1212T>G p.N404K | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100120285; called by muse, mutect2, varscan2
- CSF2RB | c.2531C>A p.P844H | Missense Mutation (SNP) | VAF 218/559 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.089); catalogued as COSV99453386; called by muse, mutect2, varscan2
- CSMD3 | c.8040G>T p.W2680C (on ENST00000297405 / NM_001363185.1; = p.W2576C on NM_052900.3) | Missense Mutation (SNP) | VAF 83/575 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52170124; called by muse, mutect2, varscan2
- CSMD3 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 68/387 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV52132305, COSV52280424, COSV99827888; called by muse, mutect2, varscan2
- CSTF1 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99410119; called by muse, mutect2, varscan2
- CTNND2 | c.1707C>A p.N569K | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100473230; called by muse, varscan2
- CUL3 | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52361183, COSV52363524; called by muse, mutect2
- CUZD1 | c.380T>G p.I127R | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100158642; called by muse, mutect2, varscan2
- CYLC1 | c.1841C>A p.P614H | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100254238; called by muse, mutect2, varscan2
- CYP2C19 | c.168+1G>T p.X56_splice | Splice Site (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100990282; called by muse, mutect2, varscan2
- CYP2C9 | c.966A>T p.K322N | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99582415; called by muse, mutect2, varscan2
- CYP2F1 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 42/67 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs568085061, COSV100462589; called by muse, mutect2, varscan2
- DACT1 | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100241661; called by muse, mutect2, varscan2
- DAP | c.58A>T p.K20* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99136277; called by muse, mutect2, varscan2
- DBN1 | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV99445704; called by muse, mutect2, varscan2
- DCC | c.2085G>C p.Q695H | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100498699; called by muse, mutect2, varscan2
- DCDC1 | c.2758C>G p.P920A (on ENST00000597505 / NM_001367979.1; = p.P27A on NM_020869.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs543287068, COSV100337954, COSV100338846; called by mutect2, varscan2
- DCDC1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100662907; called by muse, mutect2, varscan2
- DCHS1 | c.9853G>A p.E3285K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100197242; called by muse, mutect2, varscan2
- DCLK1 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV99709704; called by muse, mutect2
- DDHD2 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101240544; called by muse, mutect2, varscan2
- DDX19A | c.386+1G>T p.X129_splice | Splice Site (SNP) | VAF 41/79 reads (52%) | catalogued as COSV100156207, COSV56361216; called by muse, mutect2, varscan2
- DDX54 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100013668; called by muse, mutect2, varscan2
- DES | c.1008C>A p.D336E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.812); catalogued as rs531293539, COSV100900354; called by muse, mutect2, varscan2
- DIO3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63774490; called by muse, mutect2, varscan2
- DIP2B | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56579001; called by muse, mutect2, varscan2
- DMRT3 | c.1282C>G p.R428G | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51909084, COSV99505697; called by muse, mutect2, varscan2
- DNAH5 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99446284; called by muse, mutect2, varscan2
- DNAH9 | c.3451C>T p.H1151Y | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1337808919, COSV99304725; called by muse, mutect2, varscan2
- DNMT3B | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.009); catalogued as COSV99140592; called by muse, mutect2, varscan2
- DOCK2 | c.5068C>G p.L1690V | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as COSV99910800; called by muse, mutect2, varscan2
- DSCAM | c.1510C>A p.P504T | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.433); catalogued as COSV101259429; called by muse, mutect2, varscan2
- DSG1 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV99935673; called by muse, mutect2, varscan2
- DSG4 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100355531; called by muse, mutect2, varscan2
- DTX3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV99677640; called by muse, mutect2, varscan2
- DUSP11 | c.497A>C p.H166P | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99730882; called by muse, mutect2, varscan2
- DUXA | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs748002224, COSV101617126, COSV73729482; called by muse, mutect2, varscan2
- EGR3 | c.825C>G p.H275Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100416131; called by muse, mutect2, varscan2
- EPHA4 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915902; called by muse, mutect2, varscan2
- ERBB4 | c.3922G>T p.V1308L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs777088560, COSV100723953; called by muse, mutect2, varscan2
- ERICH3 | c.3112G>T p.A1038S | Missense Mutation (SNP) | VAF 153/270 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100443682, COSV58609655; called by muse, mutect2, varscan2
- ERN2 | c.1367C>A p.P456Q | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99890878; called by muse, mutect2, varscan2
- ESYT2 | c.1699G>T p.G567W (on ENST00000613624; = p.G491W on NM_020728.3) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99276324; called by muse, mutect2, varscan2
- EVL | c.243G>T p.W81C (on ENST00000402714 / NM_001330221.2; = p.W83C on NM_016337.3) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101233048; called by muse, mutect2, varscan2
- EXT1 | c.1149G>T p.E383D | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100983680; called by muse, mutect2, varscan2
- F13A1 | c.1626C>A p.N542K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM021264, CM980655, COSV99342473; called by muse, varscan2
- F13B | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 148/273 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV99054564; called by muse, mutect2, varscan2
- FABP5 | c.152A>T p.N51I | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.346); catalogued as rs1235407356, COSV99793028; called by muse, mutect2, varscan2
- FAM171B | c.2346G>T p.R782S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100488348; called by muse, mutect2, varscan2
- FAM83B | c.842G>T p.C281F | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.694); catalogued as COSV100174159, COSV60925086; called by muse, mutect2, varscan2
- FAM83B | c.2256C>A p.N752K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100174161, COSV60921668; called by muse, mutect2, varscan2
- FBN3 | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99560211; called by muse, mutect2, varscan2
- FBXO10 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV99446346; called by muse, mutect2, varscan2
- FBXO16 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100672191; called by muse, mutect2, varscan2
- FBXO24 | c.1611G>C p.E537D (on ENST00000241071 / NM_033506.3; = p.E575D on NM_012172.5) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.107); catalogued as COSV99575076; called by muse, mutect2, varscan2
- FER1L6 | c.3212T>C p.F1071S | Missense Mutation (SNP) | VAF 349/509 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101205562; called by muse, mutect2, varscan2
- FKBP9 | c.586T>G p.Y196D | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99639141; called by muse, mutect2, varscan2
- FLG | c.6296A>T p.Q2099L | Missense Mutation (SNP) | VAF 138/622 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100910979; called by muse, mutect2
- FLG2 | c.5164G>T p.G1722* | Nonsense Mutation (SNP) | VAF 150/433 reads (35%) | catalogued as COSV101165661; called by muse, mutect2, varscan2
- FOXI1 | c.1009T>C p.W337R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV100089126; called by muse, mutect2, varscan2
- FOXI1 | c.1010G>T p.W337L | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.749); catalogued as COSV60389297; called by muse, mutect2, varscan2
- FRMPD1 | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100899410; called by muse, mutect2, varscan2
- GABRA1 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1214814997, COSV99195751; called by muse, mutect2, varscan2
- GABRA6 | c.984del p.N329Ifs*19 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | catalogued as COSV50883337; called by mutect2, pindel, varscan2
- GALNT13 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV101222338; called by muse, mutect2, varscan2
- GALNT5 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV99374938; called by muse, mutect2, varscan2
- GARS1 | c.1847G>A p.C616Y | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101220015; called by muse, mutect2, varscan2
- GATA3 | c.1271C>G p.P424R | Missense Mutation (SNP) | VAF 59/106 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100650867, COSV60520051; called by muse, mutect2, varscan2
- GFRA1 | c.561C>A p.C187* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV100815560, COSV62611092; called by muse, mutect2, varscan2
- GIGYF2 | c.1273A>T p.R425* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV101004106; called by muse, mutect2
- GIGYF2 | c.2237T>C p.M746T | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV101004108; called by muse, mutect2, varscan2
- GINS3 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs953089244, COSV100139227; called by muse, mutect2, varscan2
- GJA1 | c.611C>A p.T204K | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56997404, COSV56997732; called by muse, mutect2, varscan2
- GLYCTK | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV99980675; called by muse, mutect2, varscan2
- GPATCH2 | c.199A>C p.K67Q | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100861359; called by muse, mutect2, varscan2
- GPR84 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.328); catalogued as COSV57209733, COSV99909970; called by muse, mutect2, varscan2
- GPRIN1 | c.1693G>T p.G565* | Nonsense Mutation (SNP) | VAF 62/169 reads (37%) | catalogued as COSV99991187; called by muse, mutect2, varscan2
- GRID2 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99938517, COSV99944684; called by muse, mutect2, varscan2
- GSR | c.849G>C p.E283D | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99645436; called by muse, mutect2, varscan2
- H2BC7 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV100587117; called by muse, mutect2, varscan2
- H2BC9 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55099027, COSV55099687, COSV99769055; called by muse, mutect2, varscan2
- HAS1 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV99708264; called by muse, mutect2
- HAS1 | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99708265; called by muse, mutect2, varscan2
- HERC4 | c.592G>T p.G198* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99516699; called by muse, mutect2, varscan2
- HKDC1 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100664417; called by muse, mutect2, varscan2
- HMGCLL1 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99231605; called by muse, mutect2, varscan2
- HRNR | c.6580C>T p.H2194Y | Missense Mutation (SNP) | VAF 64/836 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV100913095; called by muse, mutect2
- HRNR | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 176/528 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.047); catalogued as rs900388144, COSV100913096, COSV64260288; called by muse, varscan2
- HUS1B | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs759075877, COSV100033162, COSV57867304, COSV57869976; called by muse, mutect2, varscan2
- IFNA1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99439845; called by muse, mutect2, varscan2
- IGLON5 | c.675C>G p.S225R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99570502; called by muse, mutect2, varscan2
- IL17F | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100277133; called by muse, mutect2, varscan2
- IL18RAP | c.463T>A p.C155S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99961807; called by muse, mutect2, varscan2
- IL4R | c.2302G>T p.G768W | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99404842; called by muse, mutect2, varscan2
- IMPG1 | c.791del p.G264Efs*23 | Frame Shift Del (DEL) | VAF 61/151 reads (40%) | catalogued as COSV64059362; called by mutect2, pindel, varscan2
- IQGAP2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166821; called by muse, mutect2, varscan2
- ISL1 | c.701G>C p.C234S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100045154; called by mutect2, varscan2
- ISX | c.55G>T p.G19W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100434026; called by muse, mutect2, varscan2
- ITIH1 | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56254229; called by muse, mutect2, varscan2
- ITIH2 | c.1500T>G p.N500K | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100623203; called by muse, mutect2, varscan2
- KCNA5 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99363711; called by muse, mutect2, varscan2
- KCNH4 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs760667549, COSV52915356; called by muse, mutect2, varscan2
- KCNH7 | c.1415C>A p.T472K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100034577; called by muse, mutect2, varscan2
- KCNMB2 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 68/114 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100843868; called by muse, mutect2, varscan2
- KCTD8 | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759284, COSV63587877; called by muse, mutect2, varscan2
- KEAP1 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50297634; called by muse, mutect2, varscan2
- KIF2B | c.207G>C p.K69N | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99082053; called by muse, varscan2
- KIF4B | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV101469213, COSV70530872; called by muse, mutect2, varscan2
- KIR3DL1 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); catalogued as COSV100428378; called by muse, mutect2, varscan2
- KMT2A | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 118/250 reads (47%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs782789983, COSV100628236; called by muse, varscan2
- KMT2A | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 116/245 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100628238; called by muse, varscan2
- L3MBTL1 | c.1289C>A p.P430H (on ENST00000418998 / NM_001377303.1; = p.P340H on NM_015478.7) | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as COSV100916931, COSV64228183; called by muse, mutect2, varscan2
- LCE2C | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 107/280 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.1); catalogued as COSV100909402; called by muse, mutect2, varscan2
- LCP1 | c.1159T>A p.W387R | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as COSV100549759; called by muse, mutect2, varscan2
- LILRB4 | c.864C>A p.H288Q | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.276); catalogued as COSV99553572; called by muse, mutect2, varscan2
- LILRB5 | c.1756G>T p.A586S (on ENST00000449561 / NM_001081442.3; = p.A585S on NM_006840.5) | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs201610708, COSV60256617; called by muse, mutect2, varscan2
- LMOD1 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100939075; called by muse, mutect2, varscan2
- LPA | c.2914C>T p.H972Y | Missense Mutation (SNP) | VAF 290/564 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765336864, COSV100306333; called by muse, mutect2, varscan2
- LRP1B | c.12572G>T p.G4191V | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101253960; called by muse, mutect2, varscan2
- LRP1B | c.6866C>T p.T2289I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs376608050; called by muse, mutect2, varscan2
- LRP1B | c.3169G>T p.E1057* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV101253963, COSV104431626; called by muse, mutect2, varscan2
- LRP2 | c.6877G>A p.V2293I | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99787008; called by muse, mutect2, varscan2
- MACF1 | c.3727G>C p.E1243Q | Missense Mutation (SNP) | VAF 42/70 reads (60%) | catalogued as COSV100483110; called by muse, mutect2, varscan2
- MAEL | c.1048A>T p.R350W | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100901707; called by muse, mutect2, varscan2
- MAGEA8 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.755); catalogued as COSV54064189; called by muse, mutect2, varscan2
- MASP2 | c.591C>A p.S197R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.288); catalogued as COSV101280091; called by muse, mutect2, varscan2
- MCHR1 | c.1216G>C p.V406L | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs746148236, COSV99967756; called by muse, mutect2, varscan2
- MGAM | c.2470C>G p.Q824E | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV101527413; called by muse, mutect2, varscan2
- MRTFB | c.3187G>T p.D1063Y (on ENST00000571589 / NM_001365412.2; = p.D1013Y on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100370939, COSV57957603; called by muse, mutect2, varscan2
- MSRA | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100412542; called by muse, mutect2, varscan2
- MTMR1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100953850; called by muse, mutect2, varscan2
- MUC16 | c.8757C>A p.D2919E | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV101198709; called by muse, mutect2, varscan2
- MYF6 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1281930067, COSV99952714; called by muse, mutect2, varscan2
- MYH13 | c.3381A>C p.E1127D | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV99352797; called by muse, mutect2, varscan2
- MYH7 | c.5704G>T p.E1902* | Nonsense Mutation (SNP) | VAF 37/173 reads (21%) | catalogued as CM1010355, CM148166, COSV100805814; called by muse, mutect2, varscan2
- MYO16 | c.3193A>G p.I1065V | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.041); catalogued as rs1301186711, COSV100696205; called by muse, mutect2, varscan2
- MYO18B | c.3241C>A p.L1081I | Missense Mutation (SNP) | VAF 79/284 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs368601288; called by muse, mutect2, varscan2
- MYO3A | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs903557437, COSV99778772; called by muse, mutect2, varscan2
- MYOZ3 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV99770652; called by muse, mutect2
- NACA | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100771135; called by muse, mutect2, varscan2
- NBEA | c.2404A>T p.T802S | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV100077677; called by muse, varscan2
- NCKAP1L | c.1495G>T p.A499S | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV53203027, COSV99514665; called by muse, mutect2, varscan2
- NCKAP1L | c.2648C>A p.S883Y | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99514593, COSV99514675; called by muse, mutect2, varscan2
- NCKAP5L | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV100258476; called by muse, mutect2, varscan2
- NCOA7 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99996638; called by muse, mutect2, varscan2
- NDUFV3 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100446939; called by muse, mutect2, varscan2
- NFXL1 | c.2698G>T p.V900L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101040078; called by muse, mutect2, varscan2
- NLRC4 | c.1794C>A p.F598L | Missense Mutation (SNP) | VAF 71/128 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1028369592, COSV61592615; called by muse, mutect2, varscan2
- NLRP10 | c.681C>A p.C227* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV60778788, COSV60781680; called by muse, mutect2, varscan2
- NLRP5 | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 92/331 reads (28%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs745788938, COSV101173443; called by muse, mutect2, varscan2
- NOS1 | c.606C>A p.N202K | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1031458060, COSV100500190; called by mutect2, varscan2
- NOS2 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs201995183, COSV58222037; called by muse, mutect2, varscan2
- NOS2 | c.3103A>G p.K1035E | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.174); catalogued as COSV100569531; called by muse, mutect2, varscan2
- NOX3 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV50153152, COSV99342824; called by muse, mutect2, varscan2
- NPAS3 | c.1385C>A p.S462Y (on ENST00000356141 / NM_001164749.2; = p.S430Y on NM_022123.3) | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100639685, COSV100639845; called by muse, mutect2, varscan2
- NPC1L1 | c.2299C>G p.P767A | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751816093, COSV99203201; called by muse, mutect2, varscan2
- NPR1 | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100901992, COSV64117828; called by muse, mutect2, varscan2
- NR1H4 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100321036; called by muse, mutect2, varscan2
- NRG1 | c.628T>C p.C210R | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99827949; called by muse, mutect2, varscan2
- NRP1 | c.2679G>T p.L893F | Missense Mutation (SNP) | VAF 62/277 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV99587989; called by muse, mutect2, varscan2
- NSG2 | c.214-1G>T p.X72_splice | Splice Site (SNP) | VAF 41/80 reads (51%) | catalogued as COSV100292739, COSV100292784; called by muse, mutect2, varscan2
- ONECUT1 | c.641C>A p.T214N | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); catalogued as rs1305404403, COSV100009069; called by muse, varscan2
- OPCML | c.938-1G>T p.X313_splice | Splice Site (SNP) | VAF 57/114 reads (50%) | catalogued as COSV100098709; called by muse, mutect2, varscan2
- OPCML | c.665-1G>T p.X222_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | catalogued as COSV100098712; called by muse, varscan2
- OR10H3 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 95/156 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1368116075, COSV100008344; called by muse, mutect2, varscan2
- OR10S1 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV101602451; called by muse, varscan2
- OR14K1 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV99315020; called by muse, mutect2, varscan2
- OR1D2 | c.398C>A p.T133N | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV58921836; called by muse, mutect2, varscan2
- OR1J2 | c.518C>T p.T173I | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.042); catalogued as COSV100093136, COSV58945399; called by muse, mutect2, varscan2
- OR1K1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.474); catalogued as rs780109517, COSV99474178; called by muse, mutect2
- OR2V2 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100080038; called by muse, mutect2, varscan2
- OR4B1 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV100535511; called by muse, mutect2, varscan2
- OR4C46 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs759801521, COSV100060476; called by muse, mutect2, varscan2
- OR4K14 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100520350; called by muse, mutect2, varscan2
- OR4Q3 | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV59179812; called by muse, mutect2, varscan2
- OR51G2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV58992320; called by muse, mutect2, varscan2
- OR56B1 | c.743G>A p.S248N | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV100402561; called by muse, mutect2, varscan2
- OR5A1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 44/322 reads (14%) | catalogued as rs771050906, COSV57375768; called by muse, mutect2, varscan2
- OR5F1 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV53547597, COSV99558461; called by muse, mutect2, varscan2
- OR8B2 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100899356, COSV66664824; called by muse, mutect2, varscan2
- OR8J1 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100274896; called by muse, mutect2, varscan2
- ORMDL3 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 210/562 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100401480; called by muse, mutect2, varscan2
- OSBPL5 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1359722068, COSV99720132; called by muse, mutect2, varscan2
- OTOGL | c.5341T>C p.S1781P (on ENST00000547103; = p.S1772P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100086876; called by muse, mutect2, varscan2
- OTOP1 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.628); catalogued as COSV99587439; called by muse, mutect2, varscan2
- OXER1 | c.118A>T p.M40L | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV99685276; called by muse, mutect2, varscan2
- P2RX2 | c.282C>A p.D94E (on ENST00000343948 / NM_170683.4; = p.R72S on NM_012226.5) | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1167213231, COSV100265661; called by muse, mutect2, varscan2
- PABPC5 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 79/168 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442176; called by muse, mutect2, varscan2
- PADI2 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV100970881, COSV64946373; called by muse, mutect2, varscan2
- PAH | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV100187741; called by muse, mutect2, varscan2
- PAPPA2 | c.2989G>T p.G997C | Missense Mutation (SNP) | VAF 167/466 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100867685; called by muse, mutect2, varscan2
- PCDH10 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99074918, COSV99993372; called by muse, mutect2, varscan2
- PCDH15 | c.2091+1G>T p.X697_splice | Splice Site (SNP) | VAF 35/191 reads (18%) | catalogued as CS115310, COSV57421176; called by muse, mutect2, varscan2
- PCDHA11 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.158); catalogued as COSV100248560; called by muse, mutect2, varscan2
- PCDHA6 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as COSV100972165, COSV100972181; called by muse, mutect2, varscan2
- PCDHB10 | c.1910A>T p.K637M | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99503875; called by muse, mutect2, varscan2
- PCDHB12 | c.2159C>A p.A720D | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV99506943; called by muse, mutect2, varscan2
- PCDHB3 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV99164361; called by muse, mutect2, varscan2
- PCDHGA1 | c.941T>C p.M314T | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100965941; called by muse, mutect2, varscan2
- PCDHGA2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.079); catalogued as COSV53918216; called by muse, mutect2, varscan2
- PCDHGA9 | c.990G>T p.W330C | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV99533266; called by muse, mutect2, varscan2
- PCDHGB4 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99533265; called by muse, mutect2, varscan2
- PCK1 | c.1232G>T p.S411I | Missense Mutation (SNP) | VAF 51/188 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100100144; called by muse, mutect2, varscan2
- PCNX1 | c.1763G>T p.G588V | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.134); catalogued as COSV99454650; called by muse, mutect2, varscan2
- PDCD7 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 142/246 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99200127; called by muse, mutect2, varscan2
- PDCL3 | c.7-1G>T p.X3_splice | Splice Site (SNP) | VAF 35/148 reads (24%) | catalogued as COSV99959478; called by muse, mutect2, varscan2
- PDCL3 | c.342G>T p.W114C | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99959480; called by muse, mutect2, varscan2
- PDE11A | c.2424-2A>C p.X808_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99611158; called by muse, mutect2, varscan2
- PDHA2 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99756619; called by muse, mutect2, varscan2
- PDXDC1 | c.982A>C p.T328P | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100362964; called by muse, mutect2, varscan2
- PHACTR3 | c.1151C>A p.A384E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100732302; called by muse, mutect2, varscan2
- PHOX2B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99890946; called by muse, mutect2, varscan2
- PIAS1 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs763150181, COSV99986597; called by muse, mutect2, varscan2
- PIAS2 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100245090; called by muse, mutect2
- PIK3C3 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100010556, COSV56278460; called by muse, mutect2, varscan2
- PITX2 | c.915C>A p.N305K (on ENST00000354925 / NM_001204397.1; = p.N312K on NM_000325.6) | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.496); catalogued as COSV100146230; called by muse, mutect2, varscan2
- PLAAT5 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV100080385; called by muse, mutect2, varscan2
- PLCXD3 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV60616386; called by muse, mutect2, varscan2
- PLEKHA1 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.572); catalogued as rs201146571, COSV64569005; called by muse, mutect2, varscan2
- PLEKHA8 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1329363256, COSV99321470; called by muse, mutect2
- PNMA2 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101580601; called by muse, mutect2, varscan2
- PNMA8B | c.1552A>G p.T518A | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.182); catalogued as COSV100885339; called by muse, mutect2, varscan2
- POLR1F | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99748663; called by muse, mutect2, varscan2
- POLR3GL | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100996749; called by muse, mutect2, varscan2
- POTEF | c.2422G>T p.A808S | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100664673; called by muse, mutect2, varscan2
- POU6F1 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 150/332 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100374741, COSV61325803; called by muse, mutect2, varscan2
- PPEF1 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 92/181 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100583616, COSV100584170; called by muse, mutect2, varscan2
- PPFIA1 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 121/179 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99557050; called by muse, mutect2, varscan2
- PPFIA4 | c.2339A>T p.H780L (on ENST00000447715; = p.H781L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/306 reads (70%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99690336; called by muse, varscan2
- PPP1R12C | c.1823G>A p.R608K | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV99670033; called by muse, mutect2, varscan2
- PPP1R3A | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs754554464, COSV99492216; called by muse, mutect2, varscan2
- PPP2CB | c.673T>A p.S225T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99646558; called by muse, mutect2, varscan2
- PPP2R3C | c.405-2A>G p.X135_splice | Splice Site (SNP) | VAF 20/125 reads (16%) | catalogued as COSV99808619; called by muse, mutect2, varscan2
- PPP3CA | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 57/117 reads (49%) | catalogued as COSV59924664; called by muse, mutect2, varscan2
- PRAMEF14 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs770729312; called by muse, mutect2, varscan2
- PRIM1 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100590345; called by muse, mutect2, varscan2
- PSG7 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 223/479 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV101343210; called by muse, mutect2, varscan2
- PTCHD1 | c.2434C>G p.L812V | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV101037332; called by muse, mutect2
- PTPRB | c.5871T>G p.H1957Q | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99716289; called by muse, mutect2, varscan2
- QSER1 | c.1096G>A p.V366I (on ENST00000399302; = p.V495I on NM_001076786.3) | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV101234689; called by muse, varscan2
- RABL6 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1204494132, COSV100272981; called by muse, mutect2, varscan2
- RANBP2 | c.9394G>T p.G3132* | Nonsense Mutation (SNP) | VAF 26/133 reads (20%) | catalogued as COSV99311505; called by muse, mutect2, varscan2
- RBL1 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100726923; called by muse, mutect2, varscan2
- RBM23 | c.412G>T p.G138* (on ENST00000359890 / NM_001077351.2; = p.G122* on NM_018107.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV100321327; called by muse, mutect2, varscan2
- RBM45 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99617555; called by muse, mutect2, varscan2
- RFC1 | c.2750A>T p.D917V (on ENST00000381897 / NM_001363496.2; = p.D916V on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.345); catalogued as COSV100567501; called by muse, mutect2, varscan2
- RIMBP2 | c.1581C>A p.Y527* | Nonsense Mutation (SNP) | VAF 45/92 reads (49%) | catalogued as COSV55472554, COSV99898719; called by muse, mutect2, varscan2
- RNF103 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.97); catalogued as COSV99409993; called by muse, mutect2, varscan2
- RTTN | c.3757G>A p.D1253N | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV99731437; called by muse, mutect2, varscan2
- RYR1 | c.2416G>A p.G806S | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs772647350, COSV100614938; called by muse, mutect2, varscan2
- RYR1 | c.7724G>C p.R2575P | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); catalogued as COSV100614940; called by muse, mutect2, varscan2
- RYR1 | c.11096A>G p.H3699R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV100614941; called by muse, mutect2, varscan2
- RYR2 | c.10112C>A p.P3371H | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100768765; called by muse, mutect2, varscan2
- SCGB2A1 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99793700; called by muse, mutect2, varscan2
- SCML4 | c.287-2A>T p.X96_splice | Splice Site (SNP) | VAF 50/87 reads (57%) | catalogued as COSV100940185; called by muse, mutect2, varscan2
- SCN5A | c.3947G>T p.R1316L (on ENST00000333535 / NM_198056.3; = p.R1315L on NM_000335.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765907469, CM143810, COSV100346967, COSV61139531; ClinVar: uncertain significance; called by muse, mutect2
- SCNN1B | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV100225481; called by muse, mutect2, varscan2
- SEC23A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV100305138; called by muse, mutect2, varscan2
- SEMA3D | c.2250G>T p.W750C | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99406080; called by muse, mutect2, varscan2
- SEMA4D | c.1741A>C p.N581H | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV100358048; called by muse, mutect2, varscan2
- SEPTIN2 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 29/111 reads (26%) | catalogued as COSV100764919, COSV63472226; called by muse, mutect2, varscan2
- SERPINB3 | c.957del p.S320Afs*30 | Frame Shift Del (DEL) | VAF 51/152 reads (34%) | catalogued as rs1011826024; called by mutect2, pindel, varscan2
- SEZ6L | c.2509G>T p.G837C | Missense Mutation (SNP) | VAF 74/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99961561; called by muse, mutect2, varscan2
- SFMBT2 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100738588; called by muse, mutect2, varscan2
- SFTPB | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100667142; called by muse, varscan2
- SGCA | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as CM083140, COSV100006592, COSV56248782; called by muse, mutect2, varscan2
- SHANK1 | c.1190A>T p.E397V | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99520511; called by muse, mutect2, varscan2
- SHROOM3 | c.5701A>T p.R1901W | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933775; called by muse, mutect2, varscan2
- SIGLEC12 | c.652G>T p.G218C (on ENST00000291707 / NM_053003.4; = p.G100C on NM_033329.2) | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99389141; called by muse, mutect2, varscan2
- SKA3 | c.744-1G>T p.X248_splice | Splice Site (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100006211; called by muse, mutect2, varscan2
- SLC14A2 | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99675204; called by muse, mutect2, varscan2
- SLC18A1 | c.1463T>A p.L488H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV99368364; called by muse, mutect2, varscan2
- SLC1A2 | c.1450G>A p.V484M | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as COSV99554157; called by muse, mutect2
- SLC25A25 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV100895736; called by muse, mutect2, varscan2
- SLC25A41 | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs754966746, COSV99901992; called by muse, mutect2, varscan2
- SLC2A2 | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV100049158; called by muse, mutect2, varscan2
- SLC39A4 | c.650T>A p.V217D (on ENST00000301305 / NM_001374839.1; = p.V192D on NM_017767.3) | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV99433085; called by muse, mutect2
- SLC5A1 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 137/459 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV99833252; called by muse, mutect2, varscan2
- SLC5A11 | c.1771A>T p.S591C | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV100762708; called by muse, mutect2, varscan2
- SLC6A19 | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100443303; called by muse, varscan2
- SLC9C2 | c.2512A>G p.K838E | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100876618; called by muse, mutect2
- SNAPC1 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99359162; called by muse, mutect2, varscan2
- SNX13 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV101285064; called by muse, mutect2, varscan2
- SORCS1 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 23/136 reads (17%) | catalogued as COSV99544099; called by muse, mutect2, varscan2
- SORCS1 | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV99544163; called by muse, varscan2
- SPART | c.1214G>T p.C405F | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100768604; called by muse, mutect2, varscan2
- SPATA31D1 | c.4576C>A p.H1526N | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV100782577; called by muse, mutect2, varscan2
- SPEF2 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs751222846, COSV100606640; called by muse, mutect2, varscan2
- SPHKAP | c.3020C>T p.T1007M | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs752182241, COSV60868700; called by muse, mutect2, varscan2
- SPON1 | c.688C>A p.H230N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100115405; called by muse, mutect2, varscan2
- SPTA1 | c.7138C>G p.L2380V | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100778957, COSV100779064; called by muse, mutect2, varscan2
- SPTA1 | c.1352T>C p.M451T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs770050536, COSV100934552; called by muse, mutect2, varscan2
- STAB1 | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100401358; called by muse, mutect2, varscan2
- STK11 | c.859A>T p.K287* | Nonsense Mutation (SNP) | VAF 12/15 reads (80%) | catalogued as COSV58829513; called by muse, mutect2, varscan2
- STYXL2 | c.2488A>T p.N830Y | Missense Mutation (SNP) | VAF 57/91 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99608749; called by muse, mutect2, varscan2
- SUGCT | c.1239G>T p.K413N (on ENST00000335693 / NM_001193313.2; = p.K439N on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.265); catalogued as COSV100000444; called by muse, mutect2, varscan2
- SV2C | c.337A>T p.K113* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100455811; called by muse, mutect2, varscan2
- SV2C | c.902T>A p.I301N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100455814; called by muse, mutect2, varscan2
- SYNJ1 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100449061; called by muse, mutect2, varscan2
- TBC1D22B | c.1390-1G>A p.X464_splice | Splice Site (SNP) | VAF 44/196 reads (22%) | catalogued as COSV100996709; called by muse, mutect2, varscan2
- TFAP2D | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV99145739; called by muse, mutect2, varscan2
- TFAP2D | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99145740; called by muse, mutect2, varscan2
- THOC2 | c.3815A>G p.E1272G | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs1225074430, COSV55543438; called by muse, mutect2, varscan2
- THSD7A | c.3380T>C p.V1127A | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101448574; called by muse, mutect2, varscan2
- THSD7B | c.4146C>A p.S1382R (on ENST00000272643; = p.S1380R on NM_001316349.2) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99746141; called by muse, mutect2, varscan2
- TIMP1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs754631765, COSV99512133; called by muse, mutect2, varscan2
- TINAG | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as rs1403579880, COSV99448885; called by muse, mutect2, varscan2
- TMEM184B | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.669); catalogued as rs140513108, COSV100725927; called by muse, varscan2
- TMEM241 | c.856G>C p.A286P | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV101271699; called by muse, mutect2, varscan2
- TMEM67 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100018795; called by mutect2, varscan2
- TNFRSF17 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV99273166; called by muse, mutect2, varscan2
- TNKS2 | c.2374G>T p.A792S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV100861021; called by muse, mutect2, varscan2
- TNXB | c.10424G>A p.R3475H (on ENST00000647633; = p.R3228H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as rs764846659, COSV64483004; called by mutect2, varscan2
- TOPORS | c.1865A>G p.K622R | Missense Mutation (SNP) | VAF 179/421 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100859473; called by muse, mutect2, varscan2
- TRAK1 | c.1745-1G>T p.X582_splice (on ENST00000327628 / NM_001349247.2; = p.X524_splice on NM_014965.5) | Splice Site (SNP) | VAF 52/92 reads (57%) | catalogued as COSV100409827; called by muse, mutect2, varscan2
- TRAK2 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 44/168 reads (26%) | catalogued as COSV100216687; called by muse, mutect2, varscan2
- TRAV8-4 | c.45G>T p.L15= | Splice Region (SNP) | VAF 10/65 reads (15%) | catalogued as rs1341924596; called by muse, mutect2, varscan2
- TRIM10 | c.269C>G p.T90R | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100938789; called by muse, mutect2, varscan2
- TRIM58 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV100825139, COSV63569431; called by muse, varscan2
- TRPM8 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.671); catalogued as COSV100223730; called by muse, mutect2, varscan2
- TSKS | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99883025; called by muse, mutect2, varscan2
- TTLL11 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.017); catalogued as rs771565356, COSV100388533; called by muse, varscan2
- TTN | c.6304G>A p.V2102M (on ENST00000591111; = p.V2056M on NM_003319.4) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | PolyPhen possibly damaging (0.787); catalogued as rs767322897, COSV59924221; called by muse, mutect2, varscan2
- TWNK | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV54550103; called by muse, mutect2, varscan2
- TXNDC2 | c.1495G>C p.D499H (on ENST00000306084 / NM_001098529.2; = p.D432H on NM_032243.6) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100045848; called by muse, mutect2, varscan2
- TYW3 | c.426+1G>T p.X142_splice | Splice Site (SNP) | VAF 37/59 reads (63%) | catalogued as COSV100904859; called by muse, mutect2, varscan2
- UCN3 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100991688; called by muse, mutect2, varscan2
- UMOD | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100208098; called by muse, mutect2, varscan2
- UNC45B | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99268344; called by muse, varscan2
- UNC79 | c.4074C>A p.H1358Q (on ENST00000393151 / NM_001346218.2; = p.H1181Q on NM_020818.5) | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99826347; called by muse, mutect2, varscan2
- USP29 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1468743250, COSV99571857, COSV99572079; called by muse, mutect2, varscan2
- UTP25 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.872); catalogued as COSV101504732; called by muse, mutect2, varscan2
- VCAN | c.889G>C p.G297R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425009; called by muse, mutect2, varscan2
- VCAN | c.3431G>T p.G1144V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs201077399, COSV99425010; called by muse, mutect2, varscan2
- VCAN | c.6554C>A p.P2185Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99425011; called by muse, mutect2, varscan2
- VMP1 | c.311A>C p.Q104P | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.382); catalogued as COSV99230055; called by muse, mutect2, varscan2
- VNN3 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99258103; called by muse, mutect2, varscan2
- VOPP1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778225998, COSV99567037; called by muse, mutect2, varscan2
- WDR36 | c.1884G>C p.M628I | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as COSV101550954; called by muse, mutect2, varscan2
- WNT10B | c.1117T>C p.Y373H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV99975786; called by muse, mutect2, varscan2
- WNT9B | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV99255021; called by muse, mutect2, varscan2
- XIRP2 | c.8533G>T p.E2845* (on ENST00000628543; = p.E3020* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 33/138 reads (24%) | catalogued as COSV54681929, COSV99739811; called by muse, mutect2, varscan2
- XXYLT1 | c.836G>A p.G279D | Missense Mutation (SNP) | VAF 80/111 reads (72%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100118166, COSV59985007; called by muse, mutect2, varscan2
- YAE1 | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV99784890; called by muse, mutect2, varscan2
- ZBTB14 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100813423; called by muse, mutect2, varscan2
- ZBTB7C | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs200362895, COSV100134301, COSV59687690; called by muse, mutect2, varscan2
- ZC3H13 | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.564); catalogued as rs371665453; called by muse, mutect2, varscan2
- ZFAND4 | c.329-2A>T p.X110_splice | Splice Site (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100084466; called by muse, mutect2, varscan2
- ZFYVE28 | c.2617T>A p.Y873N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99342546; called by muse, mutect2, varscan2
- ZFYVE28 | c.2003C>A p.A668D | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV99342549, COSV99342876; called by muse, mutect2, varscan2
- ZMAT1 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV100858711; called by muse, mutect2, varscan2
- ZNF10 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV50213909; called by muse, mutect2, varscan2
- ZNF214 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV99547265; called by muse, mutect2, varscan2
- ZNF229 | c.2398G>T p.V800L | Missense Mutation (SNP) | VAF 180/253 reads (71%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as COSV99350160; called by muse, mutect2, varscan2
- ZNF229 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 289/418 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99350163; called by muse, varscan2
- ZNF333 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV99468898; called by muse, mutect2, varscan2
- ZNF346 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs1427157514, COSV99993112; called by muse, mutect2, varscan2
- ZNF37A | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 57/159 reads (36%) | catalogued as rs766335336, COSV100697299; called by muse, mutect2, varscan2
- ZNF382 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.421); catalogued as COSV99497531; called by muse, varscan2
- ZNF423 | c.440C>A p.P147H (on ENST00000563137 / NM_001379286.1; = p.P139H on NM_015069.4) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52190078; called by muse, mutect2, varscan2
- ZNF442 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1239384189, COSV99664261; called by muse, mutect2, varscan2
- ZNF479 | c.1008G>A p.W336* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100482578, COSV100482758, COSV100482804; called by muse, mutect2, varscan2
- ZNF502 | c.1207G>T p.G403W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99939588; called by mutect2, varscan2
- ZNF518A | c.3585C>G p.F1195L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100283395; called by muse, mutect2, varscan2
- ZNF536 | c.2474T>A p.M825K | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100834847; called by muse, mutect2, varscan2
- ZNF749 | c.1776C>G p.F592L | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100494236, COSV61946032; called by muse, mutect2
- ZNF804B | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100302413; called by muse, mutect2, varscan2
- ZNF91 | c.1566A>T p.E522D | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56086818; called by muse, mutect2, varscan2
- ZP1 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as COSV53927414; called by muse, mutect2, varscan2
- ZP4 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.12); catalogued as COSV63912612; called by muse, mutect2, varscan2
- ZRANB1 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV100669076; called by muse, mutect2, varscan2
- AC024940.1 | n.4343G>T | Splice Region (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.2206del p.M736* | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- DQX1 | c.864del p.L288Ffs*74 | Frame Shift Del (DEL) | VAF 26/172 reads (15%) | called by mutect2, pindel
- FZD10 | c.113A>T p.E38V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2
- GPRC6A | c.1786_1788delinsTT p.L596Ffs*3 | Frame Shift Del (DEL) | VAF 31/124 reads (25%) | called by pindel, varscan2*
- IGHV1-69 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- IGKV1D-42 | c.172T>A p.Y58N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- IGKV1D-8 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- IGKV2D-24 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 146/892 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, varscan2
- KLF6 | c.96_97delinsT p.W32Cfs*6 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by pindel, varscan2*
- MAGEF1 | c.914_916dup p.H305dup | In Frame Ins (INS) | VAF 8/87 reads (9%) | called by mutect2, pindel
- MAN2A1 | c.1574del p.L525* | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by pindel, varscan2
- NEB | c.2348del p.K783Sfs*21 | Frame Shift Del (DEL) | VAF 19/66 reads (29%) | called by mutect2, pindel, varscan2
- NRXN1 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6B1 | c.448del p.A150Pfs*45 | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | called by mutect2, pindel, varscan2
- RAB41 | c.597del p.P200Hfs*33 (on ENST00000374473 / NM_001363807.1; = p.P199Hfs*33 on NM_001032726.3) | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by mutect2, varscan2
- RYR3 | c.1589del p.G530Efs*23 | Frame Shift Del (DEL) | VAF 7/15 reads (47%) | called by mutect2, pindel, varscan2
- SYNE3 | c.1182dup p.L395Afs*20 | Frame Shift Ins (INS) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- TNN | c.1829dup p.K611Efs*3 | Frame Shift Ins (INS) | VAF 46/151 reads (30%) | called by mutect2, varscan2
- TNR | c.2073_2075delinsA p.D691Efs*23 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by pindel, varscan2*
- TPTE | c.1111G>T p.E371* (on ENST00000618007 / NM_199261.4; = p.E353* on NM_199259.4) | Nonsense Mutation (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- ZFPM2 | c.787del p.R263Gfs*7 | Frame Shift Del (DEL) | VAF 17/157 reads (11%) | called by mutect2, pindel, varscan2
- ABCA9 | c.3981C>T p.H1327= | Silent (SNP) | VAF 69/192 reads (36%) | catalogued as COSV100382775; called by muse, mutect2, varscan2
- ACTL9 | c.585G>T p.V195= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV100185178; called by muse, mutect2, varscan2
- ADGRA2 | c.957C>A p.G319= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100177648; called by muse, mutect2, varscan2
- ANAPC5 | c.1884T>C p.A628= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99946012; called by muse, varscan2
- ANKRD12 | c.3591G>T p.P1197= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100040931; called by muse, mutect2, varscan2
- APBA1 | c.630C>A p.R210= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs1207615179, COSV99595624, COSV99597018; called by muse, mutect2, varscan2
- ARHGEF28 | c.1227G>T p.L409= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV99708396; called by muse, mutect2, varscan2
- ATRNL1 | c.3105C>A p.T1035= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100369490; called by muse, mutect2, varscan2
- AUTS2 | c.342G>A p.V114= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV100715509; called by muse, mutect2, varscan2
- B3GALT5 | c.387C>T p.Y129= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as COSV100563315; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1833A>T p.S611= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV100863642; called by muse, mutect2, varscan2
- C14orf39 | c.1377A>T p.A459= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV100407363; called by muse, mutect2, varscan2
- C2CD3 | c.375A>G p.P125= | Silent (SNP) | VAF 135/251 reads (54%) | catalogued as COSV100486331; called by muse, mutect2, varscan2
- CASR | c.2550C>A p.P850= (on ENST00000490131; = p.P927= on NM_000388.4) | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV56134092, COSV99948591; called by muse, mutect2, varscan2
- CCSER1 | c.1503C>T p.N501= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1250245916, COSV100388829; called by muse, mutect2, varscan2
- CFAP20DC | c.1302G>T p.L434= (on ENST00000482387 / NM_001351530.2; = p.L309= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99918247; called by muse, mutect2, varscan2
- CHMP1A | c.135C>T p.A45= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV99498292; called by muse, mutect2, varscan2
- COL21A1 | c.2466C>A p.S822= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV99777785, COSV99778836; called by muse, mutect2, varscan2
- CORO2B | c.570G>T p.T190= | Silent (SNP) | VAF 33/56 reads (59%) | catalogued as COSV99962994; called by muse, mutect2, varscan2
- CYP46A1 | c.141C>A p.P47= | Silent (SNP) | VAF 47/216 reads (22%) | catalogued as COSV99952492; called by muse, mutect2, varscan2
- CYSLTR2 | c.960C>A p.L320= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99935154; called by muse, mutect2, varscan2
- DACH2 | c.1179C>T p.S393= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs1156395493, COSV100912716; called by muse, mutect2, varscan2
- DCXR | c.30G>T p.V10= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100178811; called by muse, mutect2, varscan2
- DDX41 | c.414T>C p.Y138= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV100286444; called by muse, mutect2, varscan2
- DKKL1 | c.651C>A p.T217= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs377449896, COSV99678634; called by muse, mutect2, varscan2
- DNAH5 | c.13503G>T p.R4501= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV99446283; called by muse, mutect2, varscan2
- DPP7 | c.264G>T p.S88= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs768795172, COSV100857315; called by muse, varscan2
- ECT2 | c.2577C>T p.H859= (on ENST00000392692 / NM_001349098.2; = p.H828= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 80/122 reads (66%) | catalogued as rs138783754; called by muse, mutect2, varscan2
- EDEM3 | c.1950A>G p.V650= | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100544995; called by muse, mutect2, varscan2
- ERBB4 | c.3921G>C p.V1307= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100723954, COSV100728493; called by muse, mutect2, varscan2
- F9 | c.1344C>A p.S448= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as CX900305, COSV99496416; called by muse, mutect2, varscan2
- FAS | c.99G>A p.K33= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs1350308710, COSV100570763, COSV100570773; called by muse, mutect2, varscan2
- FBN2 | c.6135A>C p.P2045= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as COSV99325661; called by muse, mutect2, varscan2
- FER1L6 | c.240C>A p.S80= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV101205559; called by muse, mutect2
- FFAR3 | c.897C>T p.G299= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs1397730750, COSV100588142; called by mutect2, varscan2
- FLG | c.4839G>T p.S1613= | Silent (SNP) | VAF 88/291 reads (30%) | catalogued as COSV64240798, COSV64246177; called by muse, mutect2, varscan2
- FLG | c.81A>T p.T27= | Silent (SNP) | VAF 86/248 reads (35%) | catalogued as rs371750406; called by muse, mutect2, varscan2
- FLNC | c.1258C>A p.R420= | Silent (SNP) | VAF 112/198 reads (57%) | catalogued as COSV100367735, COSV57954261; called by muse, mutect2, varscan2
- FSIP2 | c.17103G>A p.S5701= | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as rs267599115, COSV58078003; called by muse, mutect2, varscan2
- GALNT17 | c.678G>T p.L226= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV100352771; called by muse, mutect2, varscan2
- GALNT17 | c.1518G>A p.K506= | Silent (SNP) | VAF 61/173 reads (35%) | catalogued as rs1222702515, COSV100352772; called by muse, mutect2, varscan2
- GPC5 | c.1179G>T p.L393= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as COSV100993097; called by muse, mutect2, varscan2
- GRIN3A | c.2844C>A p.T948= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV100701399; called by muse, mutect2, varscan2
- H3C2 | c.270G>C p.V90= | Silent (SNP) | VAF 28/195 reads (14%) | catalogued as COSV52519222, COSV52520123; called by muse, mutect2, varscan2
- HRH4 | c.228G>A p.T76= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs758519592, COSV56928040, COSV56929248; called by muse, mutect2, varscan2
- IGHA1 | c.714G>A p.E238= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs755400951; called by muse, mutect2, varscan2
- IGHV2-5 | c.195C>A p.A65= | Silent (SNP) | VAF 39/119 reads (33%) | called by muse, mutect2, varscan2
- IL12RB1 | c.1788G>A p.K596= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101651878; called by muse, mutect2, varscan2
- ILF3 | c.2169C>T p.N723= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV99139434; called by muse, mutect2, varscan2
- IPCEF1 | c.345C>T p.I115= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99499304; called by muse, mutect2, varscan2
- KHDC3L | c.468C>A p.T156= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100950375; called by muse, mutect2, varscan2
- KIAA1210 | c.5124G>C p.T1708= | Silent (SNP) | VAF 78/159 reads (49%) | catalogued as COSV101273970, COSV68179677; called by muse, mutect2, varscan2
- KIF2B | c.150C>T p.N50= | Silent (SNP) | VAF 44/112 reads (39%) | catalogued as COSV99274879, COSV99276442; called by muse, varscan2
- LAMA2 | c.4272A>T p.G1424= | Silent (SNP) | VAF 78/167 reads (47%) | catalogued as COSV101370232; called by muse, mutect2, varscan2
- LIM2 | c.289C>A p.R97= (on ENST00000596399 / NM_001161748.2; = p.R139= on NM_030657.4) | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as COSV55740698, COSV99702262; called by muse, mutect2, varscan2
- LINGO2 | c.1398C>G p.G466= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100430290; called by muse, mutect2, varscan2
- LIX1 | c.438C>T p.H146= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs372586576; called by muse, mutect2, varscan2
- MAN2A1 | c.1560C>T p.I520= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV99810627; called by muse, varscan2
- MAP3K14 | c.1704G>A p.V568= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV100766409; called by muse, mutect2, varscan2
- MAPT | c.1029T>C p.P343= (on ENST00000262410 / NM_001377265.1; = p.P268= on NM_016835.4) | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99290016; called by muse, mutect2
- MARCHF11 | c.1029T>A p.T343= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100197547; called by muse, mutect2, varscan2
- MARK4 | c.393G>T p.L131= | Silent (SNP) | VAF 93/563 reads (17%) | catalogued as COSV99488025; called by muse, mutect2, varscan2
- MTG2 | c.108A>G p.P36= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100895141; called by mutect2, varscan2
- MXRA5 | c.7290G>T p.T2430= | Silent (SNP) | VAF 65/112 reads (58%) | catalogued as COSV99476094; called by muse, mutect2, varscan2
- MYO7B | c.2307C>T p.S769= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV101267954; called by muse, mutect2, varscan2
- NLRP14 | c.516C>A p.T172= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV100204677, COSV55073048; called by muse, mutect2, varscan2
- NLRP8 | c.3111G>T p.T1037= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99404872; called by muse, mutect2, varscan2
- NPAP1 | c.748C>A p.R250= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs200510789, COSV100274923, COSV61511489; called by muse, mutect2, varscan2
- NPHS1 | c.3411G>A p.P1137= | Silent (SNP) | VAF 75/276 reads (27%) | catalogued as rs767372610, COSV62286154; called by muse, mutect2, varscan2
- NSUN3 | c.211T>C p.L71= | Silent (SNP) | VAF 70/123 reads (57%) | catalogued as COSV100113155; called by muse, mutect2, varscan2
- OR10A2 | c.513G>T p.V171= | Silent (SNP) | VAF 57/195 reads (29%) | catalogued as COSV100224962; called by muse, mutect2, varscan2
- OR10A5 | c.438T>A p.A146= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as COSV100203390; called by muse, mutect2, varscan2
- OR10J3 | c.390C>G p.P130= | Silent (SNP) | VAF 48/91 reads (53%) | catalogued as COSV100171642; called by muse, mutect2, varscan2
- OR10Q1 | c.438G>A p.T146= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs779818590, COSV57470292; called by muse, mutect2, varscan2
- OR2T3 | c.669C>T p.Y223= | Silent (SNP) | VAF 107/237 reads (45%) | catalogued as COSV100613132; called by muse, mutect2, varscan2
- OR2V2 | c.723C>A p.T241= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV100080039, COSV60315728; called by muse, mutect2, varscan2
- OR4C16 | c.876G>A p.V292= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs571828412, COSV100113912; called by muse, mutect2, varscan2
- OR4X1 | c.450C>A p.G150= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100186592; called by muse, mutect2, varscan2
- OR51T1 | c.432G>A p.L144= | Silent (SNP) | VAF 48/189 reads (25%) | catalogued as COSV100434329; called by muse, varscan2
- OR52E8 | c.162G>C p.V54= | Silent (SNP) | VAF 39/150 reads (26%) | catalogued as COSV101190065, COSV66208832; called by muse, mutect2, varscan2
- OR52H1 | c.336G>T p.L112= (on ENST00000322653; = p.L118= on NM_001005289.1) | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100497281; called by muse, mutect2, varscan2
- OVCH1 | c.1992C>T p.D664= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV100548311; called by muse, mutect2, varscan2
- OXER1 | c.117C>A p.P39= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV99685277; called by muse, mutect2, varscan2
- P2RX2 | c.1365T>C p.C455= (on ENST00000343948 / NM_170683.4; = p.C357= on NM_012226.5) | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV100265663; called by muse, mutect2, varscan2
- PAPPA2 | c.1941C>A p.P647= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV62789639; called by muse, mutect2, varscan2
- PCDH8 | c.1407C>T p.A469= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100131331; called by muse, varscan2
- PCDHA1 | c.160C>T p.L54= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as COSV100974305; called by muse, mutect2, varscan2
- PCDHGA4 | c.1908C>G p.S636= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV99533259, COSV99543517; called by muse, mutect2, varscan2
- PCDHGB2 | c.753G>T p.L251= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99533263; called by muse, mutect2, varscan2
- PCNX3 | c.1296G>T p.P432= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100482282, COSV58418531; called by muse, mutect2, varscan2
- PDCD1LG2 | c.231G>A p.E77= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs1477444652, COSV101173077; called by muse, mutect2, varscan2
- PLPP4 | c.555C>A p.P185= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV100956228; called by muse, mutect2, varscan2
- PLXNA3 | c.579G>T p.A193= | Silent (SNP) | VAF 65/127 reads (51%) | catalogued as COSV100859840, COSV63755056; called by muse, mutect2, varscan2
- PMM1 | c.306G>A p.E102= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99348052; called by muse, mutect2, varscan2
- PRX | c.2352A>G p.L784= | Silent (SNP) | VAF 49/431 reads (11%) | catalogued as COSV99397552; called by muse, mutect2, varscan2
- PSKH2 | c.93C>A p.G31= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99405031; called by muse, mutect2, varscan2
- PTGER2 | c.654C>T p.V218= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs560909166; called by muse, mutect2, varscan2
- PTPRT | c.873C>A p.P291= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs758960459, COSV100625937; called by muse, mutect2, varscan2
- PTPRZ1 | c.5904C>A p.I1968= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV101099742, COSV101100842; called by muse, varscan2
- RAC2 | c.45C>T p.G15= | Silent (SNP) | VAF 84/228 reads (37%) | catalogued as COSV99969400; called by muse, mutect2, varscan2
- RAI2 | c.1554C>A p.I518= | Silent (SNP) | VAF 23/596 reads (4%) | catalogued as COSV100518196; called by muse, mutect2
- RAPGEF6 | c.2727A>G p.Q909= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs761512103, COSV99725675; called by muse, mutect2, varscan2
- RASGRP3 | c.216A>G p.L72= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV101274710; called by muse, mutect2, varscan2
- RNF130 | c.123G>A p.V41= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99992553; called by muse, mutect2, varscan2
- RTTN | c.3756G>T p.T1252= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV99731439; called by muse, mutect2, varscan2
- RYR1 | c.5370G>T p.G1790= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV100614939; called by muse, mutect2, varscan2
- SERPINB8 | c.453G>A p.G151= | Silent (SNP) | VAF 64/186 reads (34%) | catalogued as rs372582790, COSV99729010; called by muse, mutect2, varscan2
- SFMBT2 | c.1929G>T p.V643= | Silent (SNP) | VAF 105/283 reads (37%) | catalogued as COSV100738587; called by muse, mutect2, varscan2
- SFRP4 | c.237C>T p.A79= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99554291; called by muse, mutect2, varscan2
- SHANK1 | c.630G>A p.S210= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs369440211; called by muse, mutect2
- SIGLEC10 | c.1425C>A p.R475= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV59485548; called by muse, mutect2, varscan2
- SLC22A1 | c.399C>T p.S133= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100266535; called by muse, mutect2, varscan2
- SLC25A45 | c.333C>T p.F111= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs753584225, COSV99587249; called by muse, mutect2, varscan2
- SLC26A7 | c.357C>A p.V119= | Silent (SNP) | VAF 65/371 reads (18%) | catalogued as COSV99402858; called by muse, mutect2, varscan2
- SLC6A2 | c.291G>A p.P97= | Silent (SNP) | VAF 53/129 reads (41%) | catalogued as rs749112583, COSV54913330; called by muse, mutect2, varscan2
- SLC7A13 | c.1026A>T p.L342= | Silent (SNP) | VAF 256/392 reads (65%) | catalogued as rs1242554858, COSV99878608; called by muse, mutect2, varscan2
- SLC7A4 | c.1569C>A p.L523= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV100298559; called by muse, mutect2, varscan2
- SLITRK1 | c.939C>A p.G313= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV100999839, COSV65674829; called by muse, mutect2, varscan2
- SMO | c.2223C>A p.P741= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV99976355; called by muse, mutect2, varscan2
- SORBS1 | c.378C>T p.P126= (on ENST00000361941 / NM_001034954.2; = p.P85= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99527592; called by muse, mutect2, varscan2
- SOX5 | c.471C>T p.N157= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs149450279; called by muse, mutect2, varscan2
- SRGAP3 | c.2745G>T p.A915= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100840774, COSV64530482; called by muse, mutect2, varscan2
- SUPV3L1 | c.1164G>T p.R388= | Silent (SNP) | VAF 44/242 reads (18%) | catalogued as COSV100669542; called by muse, mutect2, varscan2
- TAF15 | c.312C>T p.S104= (on ENST00000605844 / NM_139215.3; = p.S101= on NM_003487.4) | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- TECTA | c.6312G>A p.G2104= | Silent (SNP) | VAF 81/153 reads (53%) | catalogued as rs561747692, COSV99879024; called by muse, mutect2, varscan2
- THAP6 | c.588C>T p.I196= | Silent (SNP) | VAF 67/101 reads (66%) | catalogued as COSV100293052; called by muse, mutect2, varscan2
- THOP1 | c.354G>T p.V118= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV100310427; called by muse, mutect2, varscan2
- TNR | c.1206C>A p.I402= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV99688248, COSV99692064; called by muse, mutect2, varscan2
- TPR | c.3579A>G p.Q1193= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV100823720; called by muse, mutect2, varscan2
- TPTE | c.1404C>T p.D468= (on ENST00000618007 / NM_199261.4; = p.D450= on NM_199259.4) | Silent (SNP) | VAF 36/232 reads (16%) | catalogued as rs141834444; called by muse, mutect2, varscan2
- TSHZ3 | c.372C>T p.N124= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as rs761901879, COSV99550915; called by muse, mutect2, varscan2
- TTLL8 | c.726G>T p.G242= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2
- U2AF2 | c.54G>T p.R18= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100454148; called by muse, mutect2, varscan2
- UBE2U | c.501T>C p.C167= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100934293; called by muse, mutect2, varscan2
- UFL1 | c.786G>A p.R262= | Silent (SNP) | VAF 61/116 reads (53%) | catalogued as COSV100990021; called by muse, mutect2, varscan2
- WDR62 | c.4167T>A p.P1389= | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as COSV99543319; called by muse, mutect2
- ZFAT | c.291G>C p.P97= | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as COSV100914333; called by muse, mutect2
- ZNF217 | c.1074G>T p.A358= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as COSV100184269; called by muse, mutect2, varscan2
- ZNF445 | c.2895C>T p.L965= | Silent (SNP) | VAF 84/178 reads (47%) | catalogued as COSV101253699; called by muse, mutect2, varscan2
- ZNF474 | c.285G>T p.R95= | Silent (SNP) | VAF 63/242 reads (26%) | catalogued as rs774196594, COSV99682044; called by muse, mutect2, varscan2
- ZNRF4 | c.759C>A p.T253= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as rs776941989, COSV99706408; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1509C>A | 3'UTR (SNP) | VAF 87/251 reads (35%) | catalogued as COSV100246989; called by muse, mutect2, varscan2
- CALCA | chr11:14967776 C>A | 3'Flank (SNP) | VAF 20/94 reads (21%) | catalogued as COSV100523934; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45117598 C>A | 3'Flank (SNP) | VAF 12/24 reads (50%) | catalogued as rs374391508, COSV50995037; called by muse, mutect2
- FAT4 | c.5176-4825G>C | Intron (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100627602; called by muse, mutect2, varscan2
- HERC2P3 | n.1590T>A | RNA (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- MAD1L1 | c.472-1446G>T | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99765403; called by muse, mutect2
- MIR1323 | n.21G>T | RNA (SNP) | VAF 50/319 reads (16%) | called by muse, mutect2, varscan2
- OSTCP1 | n.325A>T | RNA (SNP) | VAF 89/153 reads (58%) | called by muse, mutect2, varscan2
- PAX3 | chr2:222303970 G>T | 5'Flank (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54676103, COSV99735157; called by muse, mutect2
- PIK3R6 | c.-120G>T | 5'UTR (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100266145; called by muse, mutect2, varscan2
- SNORD115-20 | n.81C>A | RNA (SNP) | VAF 110/226 reads (49%) | catalogued as rs1248286608; called by muse, mutect2, varscan2
- TIFAB | c.*1C>T | 3'UTR (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- TMPRSS11F | c.1015+1863C>A | Intron (SNP) | VAF 97/158 reads (61%) | catalogued as COSV100678272, COSV100678372; called by muse, mutect2, varscan2
- TRAC | c.*359T>A | 3'UTR (SNP) | VAF 21/104 reads (20%) | called by muse, mutect2, varscan2
